Surgical pathology report (de-identified scan), TCGA case TCGA-37-A5EN, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Cureline, specimen TCGA-37-A5EN-01A (Primary Tumor).

Index	Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount per container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm. Th.)	Tumor cell %
					Male	Caucasian (White)	Lung cancer		Rt Lung	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Squamous cell carcinoma	3	4	2	0	none	n/a	70
					Male	Caucasian (White)	Lung cancer		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-O-3

Carcinoma, squamous cell NOS
8070/3
Site C66F R Lung, middle lobe
C34.2
path R Lung, NOS C34.9

HI/PA Discrepancy		✓

Source: NCI Genomic Data Commons file 350bf726-d03b-4f0c-abba-da2a042900b2 (TCGA-37-A5EN.CABD8B0D-315A-4134-BC68-E7ADD3A7CB39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).